Gene-level copy-number profile of specimen HCM-BROD-0483-C16-85M from HCMI case HCM-BROD-0483-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 50.1 years (18,303 days).
Specimen HCM-BROD-0483-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 23dd377b-8518-462e-b3a3-99c324a060df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0483-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/82e1ab8d-9959-4dee-b748-1100d6828305

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 806; copy number 2: 18,640; copy number 3: 29,135; copy number 4: 7,759; copy number 5: 1,292; copy number 6: 155; copy number 7: 44; copy number 8: 74; copy number 9: 88; copy number 10: 6; copy number 11: 16; copy number 12: 316; copy number 19: 2; copy number 28: 11; copy number 29: 3; copy number 37: 1; copy number 39: 40.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:34,555,870–34,556,820, 1 gene (within-gene range 0–3): AC027139.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 590 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,874,793–143,883,575, 1 gene, copy number 8 (within-gene range 4–8): FCGR1CP.
- chr7:79,768,028–80,226,181, 1 gene, copy number 12 (within-gene range 4–12): GNAI1.
- chr7:80,096,600–83,362,266, 26 genes, copy number 8–12: RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1.
- chr7:84,528,122–100,896,974, 320 genes, copy number 11–12 (broad region; genes not listed).
- chr7:107,765,467–108,721,601, 14 genes, copy number 12–37: SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1.
- chr7:116,275,606–117,883,675, 45 genes, copy number 19–39 (within-gene range 19–48): AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1.
- chr10:23,694,746–24,723,887, 8 genes, copy number 9 (within-gene range 2–9): KIAA1217, NUP35P1, AC063961.1, MIR603, AL356113.1, AL353583.1, ARHGAP21, RNA5SP305.
- chr12:19,089,151–20,753,386, 23 genes, copy number 7: RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1.
- chr17:34,980,512–35,377,678, 22 genes, copy number 8 (within-gene range 4–8): LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault, FNDC8, NLE1, UNC45B, AC022916.4, AC022916.2, AC022916.3, SLC35G3, AC022916.1, SLFN5, AC022706.1, AC060766.2, SLFN11, AC060766.3.
- chr17:36,210,924–39,402,523, 116 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr17:39,461,486–39,747,291, 14 genes, copy number 7–8 (within-gene range 6–8): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.

Autosomal genes at a single copy (total copy number 1): 806. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
